Somatic mutation profile of tumor specimen TCGA-CN-A6UY-01A (aliquot TCGA-CN-A6UY-01A-12D-A34J-08) from TCGA case TCGA-CN-A6UY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.4 years (20,967 days).
Specimen TCGA-CN-A6UY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd1f3a6c-e05c-4ff5-bb60-c286020b0000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A6UY-10B (Blood Derived Normal), aliquot TCGA-CN-A6UY-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cca7d975-253b-41e9-bf7c-b2c776c21bcf

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV100608874, COSV100608995; called by muse, mutect2, varscan2
- AXIN2 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100196321; called by muse, mutect2, varscan2
- BOC | c.582C>G p.D194E | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99848481; called by muse, mutect2, varscan2
- BRINP1 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs527860111, COSV56308793; called by muse, mutect2
- CARMIL2 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100576030; called by muse, mutect2, varscan2
- CCDC136 | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99922476; called by muse, mutect2, varscan2
- CDH23 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229294084, COSV99820171; called by muse, mutect2, varscan2
- CNKSR3 | c.300T>A p.S100R | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV101527229; called by muse, mutect2, varscan2
- DNTT | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100960444; called by muse, mutect2, varscan2
- ECE1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.342); catalogued as COSV99941648; called by muse, mutect2, varscan2
- ENPP6 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99698655; called by muse, mutect2, varscan2
- FER | c.1447C>G p.R483G | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99812314, COSV99812734; called by muse, mutect2, varscan2
- FUT7 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs761990061, COSV55805332; called by muse, mutect2, varscan2
- LAMB2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs574123999, COSV59730842; called by muse, mutect2, varscan2
- LYST | c.5019C>A p.F1673L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV101088935; called by muse, mutect2, varscan2
- MAGEC2 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV56000260, COSV99909515; called by muse, mutect2, varscan2
- MSH4 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99591293; called by muse, mutect2, varscan2
- NIN | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55404872; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 36/102 reads (35%) | catalogued as rs780417788; called by mutect2, varscan2
- OR2T3 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs780609392, COSV100613181, COSV62082590; called by muse, mutect2, varscan2
- PRAMEF7 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as rs779669158, COSV100435065; called by muse, mutect2, varscan2
- PTGER3 | c.982T>A p.F328I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.705); catalogued as COSV100138637; called by muse, mutect2, varscan2
- PTPRS | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs781304015, COSV53616048, COSV53629798; called by muse, mutect2, varscan2
- STAT3 | c.1201A>G p.N401D | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99232645; called by muse, mutect2, varscan2
- TAOK3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as COSV66824889; called by muse, mutect2, varscan2
- TRIM60 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.112); catalogued as rs1402292313, COSV100593975; called by muse, mutect2, varscan2
- TTN | c.73347C>G p.D24449E (on ENST00000591111; = p.D17025E on NM_003319.4) | Missense Mutation (SNP) | VAF 144/323 reads (45%) | PolyPhen probably damaging (0.945); catalogued as COSV100604577; called by muse, mutect2, varscan2
- ZBTB22 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1256073705, COSV56474538; called by muse, mutect2, varscan2
- CYLD | c.1911dup p.E638Rfs*9 | Frame Shift Ins (INS) | VAF 58/124 reads (47%) | called by mutect2, pindel, varscan2
- ABHD1 | c.648C>T p.A216= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV99574429; called by muse, mutect2, varscan2
- ADGRB3 | c.732G>A p.R244= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1417931500, COSV101000270; called by muse, mutect2, varscan2
- CDH10 | c.384C>T p.R128= | Silent (SNP) | VAF 129/212 reads (61%) | catalogued as rs768905224, COSV52568657, COSV52580692; called by muse, mutect2, varscan2
- COBLL1 | c.2709C>A p.P903= (on ENST00000392717; = p.P865= on NM_014900.5) | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as COSV99527680; called by muse, mutect2, varscan2
- CPXCR1 | c.342A>C p.S114= | Silent (SNP) | VAF 32/36 reads (89%) | catalogued as COSV99342096; called by muse, mutect2, varscan2
- DPYS | c.690G>A p.T230= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as rs374805521, COSV60907028; called by muse, mutect2, varscan2
- GOLGB1 | c.1215T>A p.L405= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as COSV100510628; called by muse, mutect2, varscan2
- GRIK2 | c.915G>A p.P305= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs145542805, COSV100028502; called by muse, mutect2, varscan2
- KCNV2 | c.834G>A p.A278= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs1429376047, COSV101172587, COSV66057578; called by muse, mutect2
- MYO15A | c.4641C>T p.S1547= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as rs370537846; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDST4 | c.1167C>T p.F389= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV99996100; called by muse, mutect2, varscan2
- PPARGC1B | c.1527G>T p.L509= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100494638; called by muse, mutect2, varscan2
- SIKE1 | c.87G>A p.L29= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV99285224; called by muse, mutect2, varscan2
- SPATA21 | c.1398T>A p.A466= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100130794; called by muse, mutect2, varscan2
- LINC01588 | n.866G>A | RNA (SNP) | VAF 84/193 reads (44%) | catalogued as rs748481395; called by muse, mutect2, varscan2
